Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A5QP, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A5QP-01A (Primary Tumor).

ILD-0-3
Carcinoma, lobular
infiltration 8520/3
Site: @ Breast, NOS
JW 4/2/13 C50.9

A. Breast, left, lumpectomy: Infiltrating lobular carcinoma, Nottingham grade I (of III) [tubules 3/3, nuclei 1/3, mitoses 1/3; Nottingham score 5/9], forming a 2.2 x 2.1 x 1.6 cm mass. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Biopsy site changes present. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.4 cm, deep margin, and 0.6 cm, anterior margin).

B. Lymph node, left, sentinel biopsy: One (of 2) axillary sentinel lymph nodes is positive with multiple (5) metastases, the largest measuring 3.5 mm in greatest dimension. Extranodal extension is focally present.

With available surgical material [AJCCpT2N1(sn)], (7th edition, 2010).

Seen in consultation with

Source: NCI Genomic Data Commons file 8a1894e8-00b7-4ad7-abe7-99b11bfd90c6 (TCGA-AR-A5QP.F2409024-D848-4B02-A371-92BEA1105EC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).